Somatic mutation profile of tumor specimen TCGA-2G-AAH0-01A (aliquot TCGA-2G-AAH0-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAH0, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 30.5 years (11,123 days).
Specimen TCGA-2G-AAH0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 33107c88-aba8-4ef2-9078-187e5a24ebec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAH0-10A (Blood Derived Normal), aliquot TCGA-2G-AAH0-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dee2bc53-4725-4b7e-83c7-630252ef558d

The open-access MAF lists 12 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 4, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EDRF1 | c.446G>T p.R149L | Missense Mutation (SNP) | VAF 20/293 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs765326292, COSV61763499; called by muse, mutect2
- GPD1L | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 10/155 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.754); catalogued as rs1216770303, COSV56989049, COSV56993353; called by muse, mutect2
- KALRN | c.5728G>T p.A1910S (on ENST00000360013 / NM_001024660.4; = p.A213S on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/52 reads (6%) | SIFT tolerated (0.76); PolyPhen benign (0.037); catalogued as COSV52253635; called by muse, mutect2
- CNTN5 | c.2995C>A p.P999T | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.192); called by muse, mutect2
- CROT | c.680A>G p.K227R | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT tolerated (0.62); PolyPhen benign (0.003); called by muse, mutect2
- MTTP | c.1611G>C p.K537N | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RBBP5 | c.98A>G p.N33S | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAX1 | c.573C>A p.I191= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as COSV101270254, COSV68271770; called by muse, mutect2, varscan2
- PCDH15 | c.4416C>T p.V1472= | Silent (SNP) | VAF 15/63 reads (24%) | called by muse, mutect2, varscan2
- RHOBTB3 | c.87G>A p.L29= | Silent (SNP) | VAF 24/299 reads (8%) | catalogued as COSV66102012; called by muse, mutect2
- TTC23 | c.630A>G p.Q210= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as rs1044135973; called by muse, mutect2, varscan2
- HDAC4 | c.866-1112_866-1111del | Intron (DEL) | VAF 9/78 reads (12%) | called by pindel, varscan2
